Somatic mutation profile of tumor specimen 0DTFRQ from CCDI case PBCJPX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Desmoplastic nodular medulloblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (531 days).
Specimen 0DTFRQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77abbcdc-5303-4b98-9c0d-29f37f48887d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTFRZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/700636f9-22fd-4582-84aa-7ba828f57e22

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, 3'UTR 1, In Frame Del 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTCH1 | c.1807C>G p.R603G | Missense Mutation (SNP) | VAF 540/2050 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV59477805; called by muse, mutect2, varscan2
- PTCH1 | c.678T>A p.C226* | Nonsense Mutation (SNP) | VAF 523/1775 reads (29%) | catalogued as COSV59493742; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 234/650 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs979918792; called by muse, mutect2, varscan2
- PTCH1 | c.3468_3485del p.A1157_L1162del | In Frame Del (DEL) | VAF 378/1869 reads (20%) | called by mutect2, varscan2
- PPT1 | c.546C>T p.A182= (on ENST00000433473; = p.A183= on NM_000310.4) | Silent (SNP) | VAF 38/738 reads (5%) | catalogued as rs1408279040, COSV65654876, COSV65655256; called by muse, mutect2
- SLC2A11 | c.-27G>T | 5'UTR (SNP) | VAF 28/1020 reads (3%) | called by muse, mutect2
- TMBIM1 | c.*24G>A | 3'UTR (SNP) | VAF 136/885 reads (15%) | catalogued as rs376693165; called by muse, mutect2, varscan2
